FM case AD13042 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/2eb8c1e0-3b15-42b5-be49-e21e28fad374

Male, 43.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
